Gene-level copy-number profile of tumor specimen ALCH-B1NU-TTP1-A from ALCHEMIST case ALCH-B1NU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.1 years (25,980 days).
Specimen ALCH-B1NU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d19cc71f-0637-44ef-9087-72e06b90618c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1NU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/ce36ab50-23b4-4345-93f3-aec9bf36bb46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,078; copy number 2: 47,429; copy number 3: 2,902; copy number 4: 3,484; copy number 5: 11; copy number 7: 2; copy number 9: 1; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,794,526–128,187,101, 1 gene, copy number 5 (within-gene range 3–5): PVT1.
- chr8:127,890,626–128,564,679, 11 genes, copy number 5–7: AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr14:105,546,610–105,588,395, 2 genes, copy number 7–9: ELK2BP, IGHA2.
- chr17:49,990,005–49,995,224, 1 gene, copy number 16: DLX3.

Autosomal genes at a single copy (total copy number 1): 2,223. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
